Somatic mutation profile of tumor specimen MP2PRT-PAUJIN-TMP1-A (aliquot MP2PRT-PAUJIN-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUJIN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (859 days).
Specimen MP2PRT-PAUJIN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34ccd20c-973b-481c-96b3-d12c63cff467.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJIN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJIN-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c3d9b1b-8fd1-4511-b1f6-d11b2839277a

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 180/239 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- DCAF1 | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1470693375; called by muse, mutect2
- MTNR1B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 216/461 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1217966168; called by muse, mutect2, varscan2
- CSTL1 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- DCAF1 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.804); called by muse, mutect2
- DNAH9 | c.1393G>T p.V465L | Missense Mutation (SNP) | VAF 116/150 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TM4SF4 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZFYVE19 | c.1145G>A p.G382D (on ENST00000355341 / NM_001077268.2; = p.G372D on NM_032850.5) | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DMXL1 | c.5172T>C p.A1724= | Silent (SNP) | VAF 73/198 reads (37%) | called by muse, mutect2, varscan2
- FABP7 | c.150G>A p.V50= | Silent (SNP) | VAF 129/265 reads (49%) | called by muse, mutect2, varscan2
- GPER1 | c.216C>T p.I72= | Silent (SNP) | VAF 162/355 reads (46%) | catalogued as rs753563915, COSV52467742; called by muse, mutect2, varscan2
- SPRED3 | c.927C>T p.D309= | Silent (SNP) | VAF 22/534 reads (4%) | catalogued as rs1450747798; called by muse, mutect2
- SPTBN4 | c.3984G>A p.A1328= | Silent (SNP) | VAF 112/216 reads (52%) | catalogued as rs144400272; called by muse, mutect2, varscan2
- ZNF423 | c.3360C>T p.P1120= (on ENST00000563137 / NM_001379286.1; = p.P1112= on NM_015069.4) | Silent (SNP) | VAF 63/451 reads (14%) | catalogued as rs372366526; called by muse, mutect2, varscan2
- CTTN | c.*499G>A | 3'UTR (SNP) | VAF 184/382 reads (48%) | catalogued as rs367662526, COSV100097669; called by muse, mutect2, varscan2
